Surgical pathology report (de-identified scan), TCGA case TCGA-KK-A8I7, project TCGA-PRAD (Prostate Adenocarcinoma), tissue source site MD Anderson Cancer Center, specimen TCGA-KK-A8I7-01A (Primary Tumor).

[page 1 of 3]
Specimen Date/Time:

***** MODIFIED REPORT - REVIEW ADDENDUM SECTION *****

DIAGNOSIS

- (A) RIGHT OBTURATOR, INTERNAL/EXTERNAL ILIAC:
Five lymph nodes, no tumor present (0/5).
(B) LEFT OBTURATOR AND INTERNAL ILIAC:
Two lymph nodes, no tumor present (0/2).
(C) LEFT EXTERNAL ILIAC:
Two lymph nodes, no tumor present (0/2).

Entire report and diagnosis completed by

ICD-O-3
Adenocarcinoma, acinar 8140/3
path
Adenocarcinoma NOS 8140/3
Site Prostate NOS C61.9
JW 11/24/13

GROSS DESCRIPTION

(A) RIGHT OBTURATOR, INTERNAL/EXTERNAL ILIAC – Received is a 5.5 x 4.3 x 1.2 cm aggregate of fibroadipose tissue. The tissue is dissected to reveal five possible lymph nodes ranging from 0.7 x 0.6 x 0.5 cm – 4.5 x 1.8 x 0.6 cm.

SECTION CODE: A1, one possible lymph node bisected; A2, one possible lymph node serially sectioned; A3, one possible lymph node serially sectioned; A4, A5, one possible lymph node serially sectioned; A6-A8, one possible lymph node serially sectioned. Entire specimen submitted.

(B) LEFT OBTURATOR AND INTERNAL ILIAC – Received is a 4.5 x 3.5 x 1.0 cm aggregate of fibroadipose tissue. The tissue is dissected to reveal two possible lymph nodes that measures 1.0 x 0.5 x 0.3 cm and 4.0 x 1.4 x 0.5 cm.

SECTION CODE: B1, one possible lymph node bisected; B2-B5, one possible lymph node serially sectioned. Entire specimen is submitted.

(C) LEFT EXTERNAL ILIAC – Received is a 4.0 x 3.1 x 1.2 cm aggregate of fibroadipose tissue. The tissue is dissected to reveal two possible lymph nodes that measure 2.7 x 1.4 x 0.5 cm and 3.5 x 1.5 x 0.7 cm.

SECTION CODE: C1, C2, one possible lymph node serially sectioned; C3, C4, one possible lymph node serially sectioned. Entire specimen is submitted.

CLINICAL HISTORY

Prostate cancer.

SNOMED CODES

"Some tests reported here may have been developed and performance characteristics determined by specifically cleared or approved by the U.S. Food and Drug Administration."

Entire report and diagnosis completed by:

. These tests have not been

Start of ADDENDUM

[page 2 of 3]
Accession: [REDACTED]
Specimen Date/Time: [REDACTED]

ADDENDUM

This modified report is being issued to provide additional information/results.

Addendum completed by

DIAGNOSIS

(D) PROSTATE AND SEMINAL VESICLES:

PROSTATIC ADENOCARCINOMA, GLEASON SCORE 9 (4+5) (SEE COMMENT).
TUMOR EXTENDING IN MULTIPLE AREAS INTO EXTRAPROSTATIC TISSUE.
TUMOR INVADING RIGHT AND LEFT SEMINAL VESICLES.
TUMOR EXTENDING TO THE MARGIN OF RESECTION.
VASCULAR/LYMPHATIC INVASION PRESENT.
PROSTATIC INTRAEPITHELIAL NEOPLASIA (PIN), HIGH GRADE.

COMMENT

The prostate gland contains three foci of prostatic adenocarcinoma. All tumor foci are located in the peripheral zone. The dominant tumor focus is located in the right anterior, right anterolateral, right lateral, right posterolateral, right posterior, mid posterior and left posterior peripheral zone with extension into the right transition zone. This tumor focus measures 2.6 x 1.6 cm in the largest cross-sectional dimension and it is present in the three cross sections of the prostate and extensively in the apex and base regions. The tumor exhibits extraprostatic extension in the right lateral surface of the prostate, right superior neurovascular bundle region and base region anterior to the right seminal vesicle. At the site of extraprostatic extension, the margin of resection is free of tumor. In the anterior apical region, tumor extends to the inked margin of resection. The extent of the positive margin is 4.0 mm. At the site of the positive margin, no extraprostatic tissue is present to identify the possible presence of extraprostatic extension. This tumor focus invades the right seminal vesicle (intraprostatic and extraprostatic portions) and left seminal vesicle (intraprostatic portion). Vascular lymphatic invasion is present within the prostate as well as within the intraprostatic portion of the left seminal vesicle. The second tumor focus is located in the left lateral and left posterolateral peripheral zone. This tumor focus measures 0.6 x 0.4 cm in the largest cross-sectional dimension and it is present in the first cross section of the prostate and focally in the apical region. The third tumor focus is located in the left lateral and left posterolateral peripheral zone. This tumor focus measures 0.7 x 0.3 cm in the largest cross-sectional dimension and it is present in the last cross section of the prostate. The non-dominant tumor foci are of lower histologic grade and confined to the prostate with negative margins.

GROSS DESCRIPTION

(D) PROSTATE AND SEMINAL VESICLES – A specimen consisting of a prostate, attached right and left seminal vesicles and attached segments of right and left vasa deferentia.

The prostate gland (4.4 x 3.1 x 3.2 cm, 33 grams, post-fixation) has the usual shape. The soft tissue present along the right posterolateral aspect of the prostate appears more abundant than along the left side. A nodule is palpated on the right side of the prostate. Serial cross sections after fixation demonstrate a possible area of tumor in the right posterolateral peripheral zone of

[page 3 of 3]
Accession: [REDACTED]

Specimen Date/Time:

the three cross sections of the prostate.

The seminal vesicles and segments of vasa deferentia are grossly free of tumor.

SECTION CODE: D1-D4, right seminal vesicle and segment of right vas deferens from the base towards the tip; D5-D7, left seminal vesicle and segment of left vas deferens from the base towards the tip; D8, prostatic base, right border; D9-D12, prostatic base, right posterior border; D13-D18, prostatic base, central portion; D19, D20, prostatic base, left border; D21-D24, prostatic base, left posterior border; D25, apex anterior; D26, D27, apex left; D28-D30, apex posterior; D31, D32, apex right; D33-D35, detached portions of margin of resection according to the specimen radiograph; D36-D47, sections of the three cross sections of the prostate according to the specimen radiograph.

The anterior aspect of the prostate is inked in green, left surface in red, right surface in yellow and posterior surface in black.

Orange ink (D37, 38, 42, 43, 46 and 47) denotes surfaces that do not represent the true margin of resection.

SNOMED CODES

T-92000, M-Y1973

Entire report and diagnosis completed by:

-----END OF REPORT-----

Criteria:	10/23/13	Yes	No

Source: NCI Genomic Data Commons file 84b6b4b1-25cf-4ce6-b241-0e4ffa90aa62 (TCGA-KK-A8I7.70BA9BA3-05E5-4B40-9D6A-BBECCAAADD81.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).